Somatic mutation profile of tumor specimen TCGA-TP-A8TV-01A (aliquot TCGA-TP-A8TV-01A-11D-A41K-08) from TCGA case TCGA-TP-A8TV, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 62.6 years (22,872 days).
Specimen TCGA-TP-A8TV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 886626e0-d67f-4d13-8a2c-3585965ea8d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TP-A8TV-10A (Blood Derived Normal), aliquot TCGA-TP-A8TV-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/56b304a6-cf3e-43e4-8fd3-a2058bcd2b6b

The open-access MAF lists 38 somatic variants for this specimen: 29 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 26, Silent 9, Frame Shift Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPOP | c.260A>G p.Y87C | Missense Mutation (SNP) | VAF 35/71 reads (49%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen possibly damaging (0.539); catalogued as rs1057519971, COSV100753468, COSV61652670, COSV61653014; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACVR1C | c.1165G>A p.A389T | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.936); catalogued as COSV99695049; called by muse, mutect2, varscan2
- BBS5 | c.446A>G p.N149S | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.133); catalogued as COSV99752208; called by muse, mutect2
- CSTF3 | c.311A>T p.Y104F | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100124341; called by muse, mutect2, varscan2
- DHX38 | c.1261A>C p.I421L | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV99194579; called by muse, mutect2, varscan2
- EFTUD2 | c.1343A>G p.K448R | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.244); catalogued as COSV101274558; called by muse, mutect2, varscan2
- EIF2AK4 | c.1424C>T p.T475M | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.797); catalogued as rs750136639, COSV55464890; called by muse, mutect2, varscan2
- ELMOD1 | c.890T>A p.M297K | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99760412; called by muse, mutect2, varscan2
- EPCAM | c.688A>C p.K230Q | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.125); catalogued as rs756801261, COSV99764320; called by muse, mutect2, varscan2
- FAM83D | c.1673A>G p.N558S | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as COSV99465503; called by muse, mutect2, varscan2
- FANCM | c.2030A>T p.D677V | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as COSV99951628; called by muse, mutect2, varscan2
- FBH1 | c.2559G>T p.R853S (on ENST00000362091 / NM_178150.3; = p.R904S on NM_032807.4) | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV100758942; called by muse, mutect2, varscan2
- GNAI1 | c.299G>A p.R100Q | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.81); catalogued as rs752261322, COSV100650627; called by muse, mutect2, varscan2
- HARS1 | c.1249C>G p.Q417E | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.903); catalogued as COSV100298305; called by muse, mutect2, varscan2
- MECOM | c.3033G>A p.M1011I (on ENST00000468789 / NM_001105078.4; = p.M1199I on NM_004991.4) | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV99245398; called by muse, mutect2, varscan2
- PLXNB1 | c.5342A>C p.K1781T | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99603418; called by muse, mutect2, varscan2
- RBM15 | c.1009del p.E337Rfs*45 | Frame Shift Del (DEL) | VAF 11/70 reads (16%) | catalogued as COSV63923497, COSV63924617; called by mutect2, pindel, varscan2
- REPS1 | c.981G>T p.W327C | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99238957; called by muse, mutect2, varscan2
- STAMBPL1 | c.501G>A p.M167I | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV100904987; called by muse, mutect2, varscan2
- STAMBPL1 | c.502C>G p.R168G | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1297419511, COSV100904988; called by muse, mutect2, varscan2
- SYDE2 | c.1717G>A p.D573N | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as COSV52316839, COSV99320650; called by muse, mutect2, varscan2
- TSN | c.453+1G>C p.X151_splice | Splice Site (SNP) | VAF 6/30 reads (20%) | catalogued as COSV101067607, COSV67605865; called by muse, mutect2, varscan2
- WDR88 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV99404341; called by muse, mutect2, varscan2
- ZMYM5 | c.1802A>G p.N601S | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated, low confidence (0.28); PolyPhen probably damaging (0.968); catalogued as COSV100562839; called by muse, mutect2
- ZNF598 | c.1738G>T p.A580S | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.82); PolyPhen benign (0.007); catalogued as rs1332184740, COSV101461983; called by muse, mutect2, varscan2
- ZNF778 | c.1970C>T p.S657F | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.554); catalogued as rs1460378981, COSV100124617; called by muse, mutect2, varscan2
- ZNF836 | c.95T>G p.L32W | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100441274; called by muse, mutect2, varscan2
- CMIP | c.2211_2212del p.C738Qfs*12 (on ENST00000537098 / NM_198390.2; = p.C644Qfs*12 on NM_030629.3) | Frame Shift Del (DEL) | VAF 18/154 reads (12%) | called by pindel, varscan2
- IGHV1OR15-9 | c.43G>T p.A15S | Missense Mutation (SNP) | VAF 52/112 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- C3 | c.2670C>T p.P890= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as rs137956083, COSV99837243; called by muse, mutect2, varscan2
- CBARP | c.222C>T p.L74= (on ENST00000382477; = p.L80= on NM_152769.3) | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV99289897; called by muse, mutect2
- KRT25 | c.867C>T p.V289= | Silent (SNP) | VAF 4/65 reads (6%) | catalogued as COSV56443988; called by muse, mutect2
- PKHD1L1 | c.9480T>C p.L3160= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV101006821; called by muse, varscan2
- QRFPR | c.1290G>A p.G430= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as rs760775621, COSV100543973; called by muse, mutect2, varscan2
- RAB3C | c.162C>T p.S54= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs1018852333, COSV99278740; called by muse, mutect2, varscan2
- RAPGEF6 | c.4182C>A p.T1394= | Silent (SNP) | VAF 7/76 reads (9%) | catalogued as rs1173535177, COSV99727904, COSV99728330; called by muse, mutect2, varscan2
- SLC27A1 | c.1089G>A p.G363= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as COSV99393636; called by muse, mutect2, varscan2
- TNKS1BP1 | c.3873C>T p.A1291= | Silent (SNP) | VAF 35/109 reads (32%) | catalogued as rs755698236, COSV100836271; called by muse, mutect2, varscan2
